Somatic mutation profile of tumor specimen MMRF_1622_1_BM_CD138pos (aliquot MMRF_1622_1_BM_CD138pos_T1_KBS5U_L05078) from MMRF case MMRF_1622, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.8 years (22,566 days).
Specimen MMRF_1622_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19faac0a-ab34-41e0-ae5f-9adb74b32c22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1622_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1622_1_PB_Whole_C2_KBS5U_L05086; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50a67c1a-66be-4c49-aec5-c4ebb51226e7

The open-access MAF lists 100 somatic variants for this specimen: 37 protein-altering or splice-affecting, 17 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 26, Silent 17, Intron 11, 3'Flank 4, 5'UTR 4, Nonsense Mutation 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 133/297 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARSJ | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.274); catalogued as rs777614872, COSV100192652; called by muse, mutect2, varscan2
- CSMD3 | c.9682T>A p.C3228S (on ENST00000297405 / NM_001363185.1; = p.C3059S on NM_052900.3) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1280927731; called by muse, mutect2, varscan2
- FYB1 | c.1165A>G p.T389A | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV60957638; called by muse, mutect2, varscan2
- HPS6 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.022); catalogued as rs773841105; called by muse, mutect2, varscan2
- IGF2R | c.6202A>G p.I2068V | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs374103856, COSV100808160; called by muse, mutect2
- IGF2R | c.6204A>G p.I2068M | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1404006947; called by muse, mutect2
- IGHV1-69 | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 61/116 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs564335126; called by muse, mutect2, varscan2
- IGHV2-70 | c.313A>T p.N105Y | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as rs377238058; called by muse, varscan2
- IGHV2-70 | c.237C>A p.Y79* | Nonsense Mutation (SNP) | VAF 59/109 reads (54%) | catalogued as rs61733526; called by muse, varscan2
- IGHV2-70 | c.234A>C p.K78N | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs376708751; called by muse, varscan2
- IGLV3-1 | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as rs184648956; called by muse, varscan2
- IGLV3-1 | c.131A>G p.D44G | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs774199094; called by muse, varscan2
- IGLV3-1 | c.334A>G p.S112G | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as rs370589387; called by muse, varscan2
- PLXDC1 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs370370043; called by muse, mutect2, varscan2
- PTPRH | c.1826G>A p.R609Q | Missense Mutation (SNP) | VAF 70/225 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201694132; called by muse, mutect2, varscan2
- SEMA5B | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 91/269 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs768121050; called by muse, mutect2, varscan2
- SHISA6 | c.1312C>T p.R438C (on ENST00000409168 / NM_001173461.1; = p.R489C on NM_207386.4) | Missense Mutation (SNP) | VAF 82/148 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1011419092, COSV69385097; called by muse, mutect2, varscan2
- SIPA1L1 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.018); catalogued as rs1230743905; called by muse, mutect2, varscan2
- SLC9A3 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as rs1423288785; called by muse, mutect2
- ZNF492 | c.221G>A p.C74Y | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs984297120; called by muse, mutect2, varscan2
- BDNF | c.50A>T p.K17M | Missense Mutation (SNP) | VAF 85/254 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- DCLK2 | c.469T>C p.Y157H | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GNAL | c.368C>T p.P123L (on ENST00000269162 / NM_001142339.3; = p.P200L on NM_182978.4) | Missense Mutation (SNP) | VAF 72/139 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GRM4 | c.2410A>G p.I804V | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- IGHV2-70D | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 44/48 reads (92%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); called by muse, varscan2
- ITPR1 | c.7520C>T p.S2507F (on ENST00000354582; = p.S2452F on NM_002222.7) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- JOSD2 | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- KLHL14 | c.1720C>A p.L574I | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NLRP10 | c.1584C>G p.N528K | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- NPAS3 | c.724C>G p.P242A (on ENST00000356141 / NM_001164749.2; = p.P210A on NM_022123.3) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- PRKDC | c.3637A>G p.K1213E | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PRRC2B | c.6038C>T p.S2013F | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- SLX4 | c.1007G>A p.C336Y | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYNCRIP | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 39/78 reads (50%) | called by muse, mutect2, varscan2
- TMUB2 | c.505C>A p.P169T (on ENST00000538716 / NM_001353177.2; = p.P149T on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF211 | c.1598G>A p.G533E (on ENST00000347302 / NM_198855.4; = p.G546E on NM_006385.5) | Missense Mutation (SNP) | VAF 75/249 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- ADAMTS19 | c.627C>T p.P209= | Silent (SNP) | VAF 92/138 reads (67%) | called by muse, mutect2, varscan2
- ASGR2 | c.804C>T p.H268= | Silent (SNP) | VAF 85/180 reads (47%) | catalogued as rs754079834, COSV99049187; called by muse, mutect2, varscan2
- CTXN2 | c.243G>A p.A81= | Silent (SNP) | VAF 115/476 reads (24%) | catalogued as rs182590178; called by muse, mutect2, varscan2
- DPYD | c.1578T>C p.T526= | Silent (SNP) | VAF 59/127 reads (46%) | called by muse, mutect2, varscan2
- GPR174 | c.222G>A p.L74= | Silent (SNP) | VAF 96/99 reads (97%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.216T>C p.P72= | Silent (SNP) | VAF 53/85 reads (62%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.174C>T p.I58= | Silent (SNP) | VAF 37/90 reads (41%) | catalogued as rs371385744; called by muse, varscan2
- IGHV2-70 | c.168C>T p.S56= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as rs367953381; called by muse, varscan2
- IGHV2-70D | c.237C>T p.F79= | Silent (SNP) | VAF 48/58 reads (83%) | called by muse, varscan2
- IGLV3-1 | c.51C>A p.S17= | Silent (SNP) | VAF 47/96 reads (49%) | catalogued as rs376572967; called by muse, varscan2
- IRGC | c.837C>T p.A279= | Silent (SNP) | VAF 73/199 reads (37%) | catalogued as rs542350356, COSV54986495; called by muse, mutect2, varscan2
- OR10J1 | c.909T>C p.A303= | Silent (SNP) | VAF 87/207 reads (42%) | called by muse, mutect2, varscan2
- OR5L2 | c.675C>A p.I225= | Silent (SNP) | VAF 9/223 reads (4%) | catalogued as COSV101004267, COSV65723787, COSV65725524; called by muse, mutect2
- PAH | c.1308C>T p.S436= | Silent (SNP) | VAF 54/104 reads (52%) | catalogued as rs867577014, COSV61016543; called by muse, mutect2, varscan2
- SLC6A7 | c.367C>T p.L123= | Silent (SNP) | VAF 19/259 reads (7%) | called by muse, mutect2
- SPATA16 | c.420A>G p.V140= | Silent (SNP) | VAF 46/138 reads (33%) | catalogued as rs751905415; called by muse, mutect2, varscan2
- TMEM19 | c.690T>C p.G230= | Silent (SNP) | VAF 36/66 reads (55%) | catalogued as rs766125523; called by muse, mutect2, varscan2
- ABCC4 | c.2536-12795T>C | Intron (SNP) | VAF 15/27 reads (56%) | catalogued as rs1230436378; called by muse, mutect2
- ADAM10 | c.207-9935C>T | Intron (SNP) | VAF 92/331 reads (28%) | called by muse, mutect2, varscan2
- ADGRA1 | c.*1053G>A | 3'UTR (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- ANKRD46 | c.636+1771T>C | Intron (SNP) | VAF 29/48 reads (60%) | called by muse, mutect2, varscan2
- BMP8B | c.*2414A>C | 3'UTR (SNP) | VAF 30/77 reads (39%) | called by muse, mutect2, varscan2
- CALN1 | c.*7792C>G | 3'UTR (SNP) | VAF 56/143 reads (39%) | called by muse, mutect2, varscan2
- CCDC169 | chr13:36227373 A>G | 3'Flank (SNP) | VAF 27/56 reads (48%) | called by muse, mutect2, varscan2
- CCDC172 | c.*44C>T | 3'UTR (SNP) | VAF 66/162 reads (41%) | catalogued as rs1275624204; called by muse, mutect2, varscan2
- CLNK | c.*39G>A | 3'UTR (SNP) | VAF 18/238 reads (8%) | catalogued as rs751560227, COSV57018108; called by muse, mutect2
- CTBP1 | chr4:1249648 C>A | 5'Flank (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- DAG1 | c.-25C>A | 5'UTR (SNP) | VAF 25/101 reads (25%) | called by muse, mutect2, varscan2
- DEUP1 | c.297+358G>A | Intron (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- EIF5A2 | c.*1867G>A | 3'UTR (SNP) | VAF 53/163 reads (33%) | catalogued as rs1270967934; called by muse, mutect2, varscan2
- EVL | c.1213+99C>G | Intron (SNP) | VAF 9/15 reads (60%) | catalogued as rs1267520022; called by muse, mutect2, varscan2
- FAM102A | c.-262C>T | 5'UTR (SNP) | VAF 64/133 reads (48%) | called by muse, mutect2, varscan2
- GPAT3 | c.*921C>T | 3'UTR (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- GTPBP10 | c.227+62del | Intron (DEL) | VAF 18/40 reads (45%) | catalogued as rs749644137; called by mutect2, varscan2
- H4C11 | c.-29_-23del | 5'UTR (DEL) | VAF 43/109 reads (39%) | called by mutect2, varscan2
- IFIT1 | c.5+467G>C | Intron (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- KCNA5 | c.-232G>A | 5'UTR (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- KCTD16 | c.*33del | 3'UTR (DEL) | VAF 30/90 reads (33%) | catalogued as rs376426438; called by mutect2, varscan2
- LAMA4 | c.503+1440C>T | Intron (SNP) | VAF 46/86 reads (53%) | catalogued as rs782676045; called by muse, mutect2, varscan2
- LMX1A | c.*1235T>A | 3'UTR (SNP) | VAF 28/76 reads (37%) | called by muse, varscan2
- MAPK8 | c.450+25A>C | Intron (SNP) | VAF 43/94 reads (46%) | called by muse, mutect2, varscan2
- PAX8 | c.*2425C>T | 3'UTR (SNP) | VAF 45/84 reads (54%) | catalogued as rs1412630619; called by muse, mutect2, varscan2
- PLEKHG3 | chr14:64748967 del G | 3'Flank (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- PRKAA2 | c.*3836T>G | 3'UTR (SNP) | VAF 40/80 reads (50%) | called by muse, mutect2, varscan2
- PTPRO | c.*459G>T | 3'UTR (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- PVR | c.*1298A>G | 3'UTR (SNP) | VAF 4/98 reads (4%) | called by muse, mutect2
- RBM19 | c.*103C>T | 3'UTR (SNP) | VAF 22/45 reads (49%) | catalogued as rs1012947249; called by muse, mutect2, varscan2
- RIMS3 | chr1:40625492 C>T | 3'Flank (SNP) | VAF 49/100 reads (49%) | called by muse, mutect2
- RTN4 | c.3477+15A>T | Intron (SNP) | VAF 24/41 reads (59%) | called by muse, mutect2, varscan2
- SEC62 | c.*3133G>A | 3'UTR (SNP) | VAF 42/114 reads (37%) | called by muse, mutect2, varscan2
- SEMA5A | c.*6497A>G | 3'UTR (SNP) | VAF 54/87 reads (62%) | called by muse, mutect2, varscan2
- SH3RF1 | c.*84A>G | 3'UTR (SNP) | VAF 58/106 reads (55%) | called by muse, mutect2, varscan2
- SLC6A19 | c.*1086A>G | 3'UTR (SNP) | VAF 42/180 reads (23%) | called by muse, mutect2, varscan2
- SRP72 | c.*931C>T | 3'UTR (SNP) | VAF 10/14 reads (71%) | called by muse, mutect2, varscan2
- STRN | c.*3337T>C | 3'UTR (SNP) | VAF 38/73 reads (52%) | called by muse, mutect2, varscan2
- TIA1 | c.*1336G>C | 3'UTR (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
- TMEM108 | c.*723T>C | 3'UTR (SNP) | VAF 118/372 reads (32%) | called by muse, mutect2, varscan2
- TMEM147 | c.77+14G>A | Intron (SNP) | VAF 55/151 reads (36%) | called by muse, mutect2, varscan2
- TRPS1 | chr8:115408668 C>T | 3'Flank (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- UQCRB | c.*4414T>C | 3'UTR (SNP) | VAF 37/92 reads (40%) | called by muse, mutect2, varscan2
- WSB2 | c.*1376C>T | 3'UTR (SNP) | VAF 4/10 reads (40%) | catalogued as rs974559119; called by muse, mutect2, varscan2
- ZFAND2B | c.*327C>T | 3'UTR (SNP) | VAF 101/228 reads (44%) | called by muse, mutect2, varscan2
- ZZEF1 | c.*237_*240del | 3'UTR (DEL) | VAF 39/92 reads (42%) | called by mutect2, pindel, varscan2
